Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81W, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81W-01A (Primary Tumor).

Short descriptive translation of the pathology report as provided by the

Date report:

Material received:

Material: left adrenal gland

Macroscopic findings

An already cut 10x6.5x7 cm encapsulated specimen. On the cut seface a yellow lesion with brown inclusions, hemorrhage and cystic transformation.

Microscopy findings:

1. Histologically at HE and PAS-staining normal adrenal tissue can be observed. The majority of the specimen consists of polygonal cells with fine granular inclusions and an eosinophilic cytoplasm. The nuclei are large and have prominent nucleopli with core inclusions. At the tumors margin collagen-rich connective tissue and fatty tissue can be observed with infiltrates of bale-like cell with a pleomorphic pattern. The granula of atypical cells stained brown at PAS, HE and Orth mixture.

Diagnosis:

10cm pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS
8700/0
Site: Adrenal gland
C74.9
JW 10/17/13

INPAQ Discrepancy		✓
Prior Discrepancy History		
Qual/Synch onous Primary sites		

Source: NCI Genomic Data Commons file 2e646730-cdc6-4aae-8b84-07f999f27e87 (TCGA-WB-A81W.0B265767-27FD-4528-B06F-C7705F508375.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).